Somatic mutation profile of tumor specimen TCGA-G9-6385-01A (aliquot TCGA-G9-6385-01A-11D-1786-08) from TCGA case TCGA-G9-6385, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,399 days).
Specimen TCGA-G9-6385-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03101ea1-b737-4927-96e5-77b9ab69b063.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6385-10A (Blood Derived Normal), aliquot TCGA-G9-6385-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/410e30ea-cf1c-486d-ae23-49ec039bce5f

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LGR5 | c.1919T>C p.I640T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372546802; called by muse, mutect2, varscan2
- OR2G6 | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58574974; called by muse, mutect2, varscan2
- PCDHGB7 | c.1340A>G p.D447G | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53975886; called by muse, mutect2, varscan2
- NOTCH4 | c.5412G>A p.A1804= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV66681770; called by muse, mutect2
- SMU1 | c.912G>A p.R304= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV68140017; called by muse, mutect2
